Somatic mutation profile of tumor specimen ALCH-B2YG-TTP1-A (aliquot ALCH-B2YG-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2YG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.0 years (28,841 days).
Specimen ALCH-B2YG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62490656-5495-4683-8e2d-e2afcf9e533b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2YG-NB1-A (Blood Derived Normal), aliquot ALCH-B2YG-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/361890c3-e638-4e08-9533-bd8c4822377b

The open-access MAF lists 135 somatic variants for this specimen: 88 protein-altering or splice-affecting, 37 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 37, Nonsense Mutation 10, Splice Site 4, Intron 3, Splice Region 3, RNA 2, 3'UTR 2, 5'Flank 2, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+1G>T p.X1010_splice | Splice Site (SNP) | VAF 140/514 reads (27%) | hotspot (GDC flag); catalogued as rs869320707, COSV59256499, COSV59256681, COSV59259384, COSV59260405; ClinVar: risk factor; called by muse, mutect2, varscan2
- AFF4 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 101/490 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs975222814; called by muse, mutect2, varscan2
- CEACAM6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 21/728 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs145319104; called by muse, mutect2
- CEP128 | c.234+1G>A p.X78_splice | Splice Site (SNP) | VAF 56/361 reads (16%) | catalogued as rs985182575; called by muse, mutect2, varscan2
- CRYBA4 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as rs766228651, COSV61321401, COSV61322710; called by muse, mutect2
- CSMD3 | c.10628G>T p.G3543V (on ENST00000297405 / NM_001363185.1; = p.G3374V on NM_052900.3) | Missense Mutation (SNP) | VAF 92/670 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52115921, COSV99834043; called by muse, mutect2, varscan2
- DEFB123 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV66232921; called by mutect2, varscan2
- EGFL7 | c.78C>T p.P26= | Splice Region (SNP) | VAF 7/68 reads (10%) | catalogued as rs771363151; called by muse, mutect2, varscan2
- GLYCTK | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.893); catalogued as rs1429984147; called by muse, mutect2, varscan2
- INTS1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 7/117 reads (6%) | catalogued as COSV101248196; called by muse, mutect2
- KALRN | c.6315G>T p.M2105I (on ENST00000360013 / NM_001024660.4; = p.M408I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/603 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV52260754; called by muse, mutect2, varscan2
- KCNMA1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 62/453 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as rs142858967, COSV54238165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5C | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101276228; called by muse, mutect2, varscan2
- MYH1 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 50/550 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs201766006; called by muse, mutect2
- OR13C3 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 100/594 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66165798; called by muse, mutect2, varscan2
- OR1S2 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs538692208; called by muse, mutect2
- OR2T2 | c.509G>C p.C170S | Missense Mutation (SNP) | VAF 69/743 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100737705; called by muse, mutect2, varscan2
- OR51V1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1354019640; called by muse, mutect2
- OTOGL | c.3578C>T p.S1193L (on ENST00000547103; = p.S1184L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV101509336, COSV72007236; called by muse, mutect2
- PASD1 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV100949315; called by muse, mutect2, varscan2
- PLG | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 88/639 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57518504; called by muse, mutect2, varscan2
- PRAMEF10 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52434573; called by muse, mutect2, varscan2
- RMDN1 | c.357G>T p.W119C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032139932; called by muse, mutect2, varscan2
- SEMA4C | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV59691179; called by muse, mutect2
- SFRP5 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV56603657; called by muse, mutect2
- SLC6A18 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 94/652 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.074); catalogued as COSV57249849; called by muse, mutect2, varscan2
- TJP1 | c.4621C>A p.R1541S | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV100632756; called by muse, mutect2
- TMEM81 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs927804630; called by muse, mutect2, varscan2
- TNN | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 54/515 reads (10%) | catalogued as rs1294229257, COSV53432834; called by muse, mutect2
- USH1C | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs760448018; called by muse, mutect2, varscan2
- ZNF585A | c.1891G>C p.E631Q (on ENST00000292841 / NM_001288800.2; = p.E576Q on NM_152655.3) | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV53065495, COSV99492640; called by muse, mutect2, varscan2
- AASS | c.202C>G p.H68D | Missense Mutation (SNP) | VAF 30/1062 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); called by muse, mutect2
- ABCA12 | c.3476T>A p.I1159N (on ENST00000272895 / NM_173076.3; = p.I841N on NM_015657.3) | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ADAMTS1 | c.2418_2419insC p.A807Rfs*9 | Frame Shift Ins (INS) | VAF 24/192 reads (13%) | called by mutect2, pindel*
- ADGRG4 | c.5898del p.T1967Hfs*12 | Frame Shift Del (DEL) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- ATP6V0D2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CACNA1C | c.1887G>T p.K629N | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CARD14 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC185 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CLSTN2 | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 104/734 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.188); called by muse, varscan2
- CNTNAP4 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COX6B1 | c.187T>G p.S63A | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- CRACR2A | c.2175G>T p.K725N | Missense Mutation (SNP) | VAF 54/398 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.10628-1G>T p.X3543_splice (on ENST00000297405 / NM_001363185.1; = p.X3374_splice on NM_052900.3) | Splice Site (SNP) | VAF 91/667 reads (14%) | called by muse, mutect2, varscan2
- E2F3 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 113/861 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ERICH3 | c.1818C>A p.H606Q | Missense Mutation (SNP) | VAF 52/574 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); called by muse, mutect2
- FAM189A1 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); called by muse, mutect2
- FASTKD5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.10249C>A p.Q3417K | Missense Mutation (SNP) | VAF 98/855 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- FOXB2 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.55); called by muse, varscan2
- GIMAP7 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2
- HECW1 | c.2681C>T p.T894I | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2
- ILKAP | c.894C>G p.Y298* | Nonsense Mutation (SNP) | VAF 17/586 reads (3%) | called by muse, mutect2
- ITGB3 | c.22del p.R8Gfs*18 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel, varscan2
- KALRN | c.6756G>C p.R2252S (on ENST00000360013 / NM_001024660.4; = p.R555S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNC3 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.071); called by muse, mutect2
- KIF21A | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- MAGEA3 | c.-64C>A | Splice Region (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- MAP4K3 | c.1928C>G p.P643R | Missense Mutation (SNP) | VAF 39/501 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2
- MTR | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 67/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA16 | c.1721C>A p.T574N | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NETO1 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 33/536 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NRXN1 | c.3178G>T p.G1060* | Nonsense Mutation (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- NUDT19 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR14A16 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5B2 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PKHD1 | c.11597C>A p.S3866Y | Missense Mutation (SNP) | VAF 97/696 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- POMK | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 136/486 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- PPFIA2 | c.2230C>A p.L744M | Missense Mutation (SNP) | VAF 118/772 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPF39 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRB | c.3329G>T p.G1110V | Missense Mutation (SNP) | VAF 63/848 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBMXL2 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 97/773 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGS22 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 72/610 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- SCML4 | c.107T>A p.L36* | Nonsense Mutation (SNP) | VAF 46/247 reads (19%) | called by muse, varscan2
- SGO2 | c.3542C>T p.S1181F | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SLC35C2 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 64/561 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPOCK3 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 60/573 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SYMPK | c.3721G>T p.E1241* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- TEFM | c.495+5A>T | Splice Region (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2
- TFAM | c.538-1G>A p.X180_splice | Splice Site (SNP) | VAF 28/526 reads (5%) | called by muse, mutect2
- TG | c.4765G>C p.V1589L | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TOR1B | c.298A>T p.K100* | Nonsense Mutation (SNP) | VAF 76/535 reads (14%) | called by muse, mutect2, varscan2
- TRIM61 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 36/825 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); called by muse, mutect2
- YTHDC1 | c.929T>G p.I310S | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZFR2 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 32/280 reads (11%) | called by muse, mutect2, varscan2
- ZNF300 | c.1807A>T p.K603* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ZNF404 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ZPLD1 | c.993C>A p.S331R (on ENST00000466937 / NM_001329788.1; = p.S347R on NM_175056.2) | Missense Mutation (SNP) | VAF 72/740 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.156); called by muse, mutect2
- ABCB1 | c.1689A>T p.T563= | Silent (SNP) | VAF 253/825 reads (31%) | called by muse, mutect2, varscan2
- APC | c.1686G>T p.T562= | Silent (SNP) | VAF 160/915 reads (17%) | called by muse, mutect2, varscan2
- ARG1 | c.627C>A p.G209= | Silent (SNP) | VAF 63/519 reads (12%) | called by muse, mutect2, varscan2
- BARD1 | c.48C>T p.S16= | Silent (SNP) | VAF 42/275 reads (15%) | catalogued as rs770753803; ClinVar: likely benign; called by muse, mutect2, varscan2
- CABIN1 | c.1671G>A p.L557= | Silent (SNP) | VAF 38/913 reads (4%) | called by muse, mutect2
- CCT8 | c.1458C>T p.V486= | Silent (SNP) | VAF 38/289 reads (13%) | catalogued as rs960777085; called by muse, mutect2, varscan2
- CGNL1 | c.1359G>T p.G453= | Silent (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
- DENND2B | c.270C>T p.P90= | Silent (SNP) | VAF 36/288 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.4266C>T p.V1422= | Silent (SNP) | VAF 52/403 reads (13%) | called by muse, varscan2
- ELOVL1 | c.42C>T p.H14= | Silent (SNP) | VAF 28/604 reads (5%) | catalogued as rs373810841; called by muse, mutect2
- EPHA3 | c.2481G>A p.E827= | Silent (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- EPHA8 | c.897C>T p.S299= | Silent (SNP) | VAF 29/346 reads (8%) | catalogued as rs372203085, COSV51306118; called by muse, mutect2
- GJB5 | c.792C>A p.P264= | Silent (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- GJC2 | c.1239G>A p.E413= | Silent (SNP) | VAF 45/361 reads (12%) | catalogued as rs1384922398; called by muse, mutect2, varscan2
- GPR135 | c.174A>T p.A58= | Silent (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- GPR148 | c.216G>T p.V72= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- HOXA10 | c.702G>A p.Q234= | Silent (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- KIF23 | c.2250G>A p.Q750= | Silent (SNP) | VAF 34/548 reads (6%) | called by muse, mutect2
- KRIT1 | c.1134A>G p.P378= | Silent (SNP) | VAF 74/550 reads (13%) | called by muse, mutect2, varscan2
- LRRC32 | c.1143C>T p.G381= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs777882667; called by muse, mutect2, varscan2
- NETO1 | c.591C>T p.S197= | Silent (SNP) | VAF 35/791 reads (4%) | catalogued as rs775844376, COSV55011126; called by muse, mutect2
- NSD1 | c.5091G>T p.R1697= | Silent (SNP) | VAF 140/872 reads (16%) | called by muse, mutect2, varscan2
- OR1L1 | c.906T>C p.Y302= (on ENST00000373686; = p.Y252= on NM_001005236.3) | Silent (SNP) | VAF 48/351 reads (14%) | catalogued as rs1487531716; called by muse, mutect2, varscan2
- PCDH15 | c.273G>A p.K91= | Silent (SNP) | VAF 85/702 reads (12%) | catalogued as rs982276851, COSV57261949; called by muse, mutect2, varscan2
- PCDH19 | c.1479G>C p.V493= | Silent (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1677G>A p.A559= | Silent (SNP) | VAF 29/516 reads (6%) | catalogued as rs772392717, COSV53960042; called by muse, mutect2
- PPP4R3A | c.1428C>T p.F476= (on ENST00000554943 / NM_001366432.1; = p.F463= on NM_001284280.1) | Silent (SNP) | VAF 55/332 reads (17%) | catalogued as rs774507308, COSV100466139; called by muse, mutect2, varscan2
- RBM19 | c.279C>T p.A93= | Silent (SNP) | VAF 111/670 reads (17%) | called by muse, mutect2, varscan2
- SHLD3 | c.168A>T p.S56= | Silent (SNP) | VAF 56/228 reads (25%) | called by muse, mutect2, varscan2
- SLC12A6 | c.492G>A p.K164= (on ENST00000354181 / NM_001365088.1; = p.K113= on NM_005135.2) | Silent (SNP) | VAF 68/1124 reads (6%) | catalogued as rs1195819037; called by muse, mutect2
- SLITRK3 | c.1731C>A p.I577= | Silent (SNP) | VAF 64/543 reads (12%) | catalogued as COSV53848461; called by muse, mutect2, varscan2
- SSR2 | c.423G>A p.R141= | Silent (SNP) | VAF 32/275 reads (12%) | catalogued as rs368464476; called by muse, mutect2, varscan2
- ST18 | c.777G>A p.P259= | Silent (SNP) | VAF 46/409 reads (11%) | catalogued as rs765013460; called by muse, mutect2, varscan2
- STAG1 | c.723T>C p.S241= | Silent (SNP) | VAF 31/316 reads (10%) | called by muse, mutect2, varscan2
- TBX5 | c.66G>C p.L22= | Silent (SNP) | VAF 69/549 reads (13%) | called by muse, mutect2, varscan2
- TREML1 | c.90G>T p.V30= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- VWC2 | c.381C>A p.A127= | Silent (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2377-96A>T | Intron (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- APOOP5 | n.199T>A | RNA (SNP) | VAF 25/393 reads (6%) | called by muse, mutect2
- BRCA2 | c.*22A>G | 3'UTR (SNP) | VAF 54/271 reads (20%) | catalogued as rs1566261689; called by muse, mutect2, varscan2
- CD320 | c.*46G>T | 3'UTR (SNP) | VAF 51/291 reads (18%) | called by muse, mutect2, varscan2
- IGFALS | chr16:1794902 G>A | 5'Flank (SNP) | VAF 76/452 reads (17%) | catalogued as rs903940893; called by muse, mutect2, varscan2
- MEMO1 | c.438-1120C>T | Intron (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- PPA2 | c.222+414A>G | Intron (SNP) | VAF 18/351 reads (5%) | catalogued as rs373676560; called by muse, mutect2
- RNA5-8SP2 | chr16:34159391 C>A | 5'Flank (SNP) | VAF 11/83 reads (13%) | called by muse, varscan2
- RPS27 | c.-4G>T | 5'UTR (SNP) | VAF 45/368 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.11050G>T | RNA (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
